Somatic mutation profile of tumor specimen TCGA-AO-A0JC-01A (aliquot TCGA-AO-A0JC-01A-11W-A071-09) from TCGA case TCGA-AO-A0JC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.1 years (23,404 days).
Specimen TCGA-AO-A0JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5f81b0a-7108-49ed-b624-319e71f88797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JC-10A (Blood Derived Normal), aliquot TCGA-AO-A0JC-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e8d4b76-cdf4-4e68-b919-094120782dcc

The open-access MAF lists 154 somatic variants for this specimen: 115 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 34, Nonsense Mutation 10, Splice Site 2, 5'Flank 2, 3'UTR 2, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 15/431 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057519827, COSV52782264; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 10/227 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- AARS1 | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV55749861; called by muse, mutect2, varscan2
- ABCC9 | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.027); catalogued as COSV99687524; called by muse, mutect2
- ADGRV1 | c.5767G>C p.E1923Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.372); catalogued as COSV67996468; called by muse, mutect2, varscan2
- ALK | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101202787, COSV66567188; called by muse, mutect2
- ANGPTL1 | c.1182C>G p.F394L | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.099); catalogued as COSV99328417; called by muse, mutect2
- ANKRD17 | c.3185C>A p.S1062Y | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100430072; called by muse, mutect2
- ANKRD55 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV100591717; called by muse, mutect2
- AP2B1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV99251778; called by muse, mutect2
- ATF2 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99909071; called by muse, mutect2
- ATF7IP | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | catalogued as COSV99662218; called by muse, mutect2
- BCHE | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52264165; called by muse, mutect2
- CCNDBP1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV99543912; called by muse, mutect2
- CDH24 | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.981); catalogued as COSV57464034; called by muse, mutect2, varscan2
- CDK17 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 5/140 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99703146; called by muse, mutect2
- CHD7 | c.6877G>T p.D2293Y | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV101418512; called by muse, mutect2
- CKAP5 | c.5000C>T p.S1667F (on ENST00000529230 / NM_001008938.4; = p.S1607F on NM_014756.3) | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1369203297, COSV100371537; called by muse, mutect2
- CLCN5 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV100260426; called by muse, mutect2
- CNTNAP4 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV56703385; called by muse, mutect2
- CREBRF | c.1521G>C p.K507N | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV51636805; called by muse, mutect2, varscan2
- DAB1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); catalogued as COSV100140945, COSV59729385; called by muse, mutect2
- DMXL1 | c.5945C>G p.S1982* | Nonsense Mutation (SNP) | VAF 18/298 reads (6%) | catalogued as rs1288956351, COSV100225156; called by muse, mutect2
- DST | c.7186G>A p.D2396N | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1234182030, COSV99760576; called by muse, mutect2
- DTX3L | c.564G>C p.L188F | Missense Mutation (SNP) | VAF 6/167 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV99950171; called by muse, mutect2
- DYRK1A | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV100118360; called by muse, mutect2
- EPHA7 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV65181898; called by muse, mutect2
- EPHB2 | c.1519del p.Q507Rfs*22 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as COSV101006907; called by mutect2, pindel, varscan2
- EPS8 | c.1785G>T p.L595F | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99843783; called by muse, mutect2
- FAM174A | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs779059148, COSV100444659; called by muse, mutect2
- FERMT1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV54093904; called by muse, mutect2
- FNDC3A | c.1842G>A p.M614I (on ENST00000492622 / NM_001079673.2; = p.M558I on NM_014923.5) | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101256929; called by muse, mutect2
- GALNT8 | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV99363306; called by muse, mutect2
- GEMIN5 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV99594390; called by muse, mutect2
- GGCT | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99139224; called by muse, mutect2
- GLRA1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.651); catalogued as COSV99199719; called by muse, mutect2
- GRIN2A | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58020558; called by muse, mutect2
- GRIPAP1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs1372314814, COSV100904407; called by muse, mutect2
- HARS2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99218190; called by muse, mutect2
- HDLBP | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as rs767410138, COSV100190378, COSV100191991; called by muse, mutect2
- HTT | c.5776G>C p.D1926H | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100751336; called by muse, mutect2
- IL16 | c.3262G>C p.E1088Q (on ENST00000302987 / NM_172217.5; = p.E387Q on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as COSV100268243; called by muse, mutect2
- INTU | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100081470; called by muse, mutect2
- IPO11 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321534; called by muse, mutect2
- IRS4 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100929795; called by muse, mutect2
- KIAA1109 | c.1053-1G>C p.X351_splice | Splice Site (SNP) | VAF 10/194 reads (5%) | catalogued as COSV99179658; called by muse, mutect2
- LBR | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99687789; called by muse, mutect2
- LRP1B | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV101261808, COSV67206799; called by muse, mutect2
- MAGED1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.351); catalogued as COSV58516874; called by muse, mutect2
- MAP3K1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV68124575; called by muse, mutect2
- MED12L | c.6391C>T p.Q2131* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99198603; called by muse, mutect2
- MSN | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 13/402 reads (3%) | catalogued as COSV100814325; called by muse, mutect2
- MTHFD2 | c.254T>A p.V85D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99903236; called by muse, mutect2
- MUC16 | c.9111G>C p.E3037D | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV101201966, COSV67457089; called by muse, mutect2
- NBEAL1 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV101495707, COSV101495804; called by muse, mutect2
- NEPRO | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 15/210 reads (7%) | catalogued as rs750242649, COSV58724558; called by muse, mutect2
- NFE2L1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100671760; called by muse, mutect2
- NIPBL | c.6187G>A p.E2063K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1324433590, COSV56945564, COSV99239406, COSV99242997; called by muse, mutect2
- NLRP11 | c.1788G>C p.L596F | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV100789820; called by muse, mutect2
- NLRP5 | c.2160G>C p.L720F | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV101173918; called by muse, mutect2
- NOMO1 | c.2998G>C p.E1000Q | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV99814939; called by muse, mutect2
- OR2AG1 | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100265000; called by muse, mutect2
- OR2L2 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 54/1054 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.404); catalogued as COSV100824353, COSV63547987; called by muse, mutect2
- OR2M2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 84/1124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100677225, COSV100677329, COSV62899446; called by muse, mutect2
- OR5L2 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 28/736 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV101004434; called by muse, mutect2
- ORC2 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99309785; called by muse, mutect2
- PGR | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54811632, COSV99679246; called by muse, mutect2
- PIK3CB | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100006192, COSV56687147; called by muse, mutect2
- PIP5K1A | c.680A>G p.Y227C (on ENST00000368888 / NM_001135638.2; = p.Y214C on NM_003557.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100576630; called by muse, mutect2
- PMPCB | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99971468; called by muse, mutect2
- POGZ | c.2235G>C p.M745I | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV99653304; called by muse, mutect2
- PPP4R3A | c.2345G>C p.G782A (on ENST00000554943 / NM_001366432.1; = p.G769A on NM_001284280.1) | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV100466627; called by muse, mutect2
- PRAMEF4 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.894); catalogued as COSV99340305; called by muse, mutect2
- PRKD3 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52212455, COSV99306867; called by muse, mutect2
- PRSS12 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV56609121; called by muse, mutect2
- PRUNE2 | c.4305G>T p.M1435I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100945239; called by muse, mutect2
- RAF1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV99313515; called by muse, mutect2
- RANBP3L | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs868141616, COSV56956649; called by muse, mutect2
- RAPH1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV100052034; called by muse, mutect2
- RDX | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV100563129; called by muse, mutect2
- RFX5 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51841268, COSV99303379; called by muse, mutect2
- RIC1 | c.3655G>T p.E1219* | Nonsense Mutation (SNP) | VAF 12/183 reads (7%) | catalogued as COSV99318127; called by muse, mutect2
- RPL10 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1557185299, COSV99186366; called by muse, mutect2
- RSBN1 | c.1194G>C p.L398F | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV99793656; called by muse, mutect2
- SCMH1 | c.833G>A p.G278E (on ENST00000326197 / NM_001031694.2; = p.G231E on NM_012236.4) | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100402264; called by muse, mutect2
- SECISBP2L | c.1388C>T p.S463L (on ENST00000559471 / NM_001193489.2; = p.S418L on NM_014701.4) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99961078; called by muse, mutect2
- SF3B1 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.285); catalogued as COSV100136012; called by muse, mutect2
- SIPA1L2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53394570, COSV99479889; called by muse, mutect2
- SKIV2L | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs746481824, COSV100952542, COSV64812555; called by muse, mutect2
- SLC22A14 | c.942C>A p.I314= | Splice Region (SNP) | VAF 7/84 reads (8%) | catalogued as COSV56199798, COSV99828389; called by muse, mutect2
- SLC22A14 | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99827997; called by muse, mutect2
- SLC26A9 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100536900; called by muse, mutect2
- SLC30A5 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101173665; called by muse, mutect2
- SLK | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 9/287 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100212179; called by muse, mutect2
- SNRNP48 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100673074; called by muse, mutect2
- SORL1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99495704; called by muse, mutect2
- SULT1E1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV56946307; called by muse, mutect2
- SYT3 | c.1105C>A p.Q369K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV100144361; called by muse, mutect2
- THSD4 | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 5/109 reads (5%) | catalogued as COSV99967372; called by muse, mutect2
- TMEM117 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV56901717, COSV99863883; called by muse, mutect2
- TMSB4X | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV101020371; called by muse, mutect2
- TRAIP | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV100513469; called by muse, mutect2
- TXLNB | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100625203; called by muse, mutect2
- ULK4 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100095608, COSV57215201; called by muse, mutect2
- USP34 | c.6682-1G>C p.X2228_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV101277263; called by muse, mutect2
- ZDHHC17 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100602324; called by muse, mutect2
- ZFP30 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100666100; called by muse, mutect2
- ZNF280C | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100921283; called by muse, mutect2, varscan2
- ZNF283 | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 14/270 reads (5%) | catalogued as COSV100191126, COSV61030520; called by muse, mutect2
- ZNF461 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100831502; called by muse, mutect2
- ZNF560 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 6/178 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV56867231; called by muse, mutect2
- ZNF816-ZNF321P | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100008502; called by muse, mutect2
- SEMA3D | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- TNKS2 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- YLPM1 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- ARHGEF11 | c.2436C>T p.L812= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100169040; called by muse, mutect2
- ATP11C | c.3261G>A p.L1087= | Silent (SNP) | VAF 11/215 reads (5%) | catalogued as COSV100558757; called by muse, mutect2
- B3GNT3 | c.774G>A p.V258= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1484520480, COSV57954056; called by muse, mutect2, varscan2
- CACNA1E | c.3807C>T p.I1269= | Silent (SNP) | VAF 15/257 reads (6%) | catalogued as COSV100705631; called by muse, mutect2
- CCNF | c.789C>T p.A263= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV99564263; called by muse, mutect2
- CDK5RAP2 | c.201C>T p.I67= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV62578714; called by muse, mutect2
- DLG5 | c.1641G>A p.L547= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100967948, COSV64950422; called by muse, mutect2
- DLK2 | c.948C>A p.L316= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99768083; called by muse, mutect2
- EIF3E | c.30C>T p.I10= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV55201119, COSV55202044, COSV55202459; called by muse, mutect2
- FHL2 | c.768C>G p.L256= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100363208; called by muse, mutect2
- FHOD3 | c.2274G>A p.G758= (on ENST00000359247 / NM_001281739.3; = p.G775= on NM_025135.5) | Silent (SNP) | VAF 10/270 reads (4%) | catalogued as COSV99943335; called by muse, mutect2
- FMR1 | c.1443C>T p.H481= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV99503621; called by muse, mutect2
- GALNT5 | c.783G>A p.Q261= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV99375648; called by muse, mutect2
- GDE1 | c.948C>G p.S316= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99572931; called by muse, mutect2
- HEATR9 | c.1311C>T p.F437= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- IL16 | c.2658C>T p.L886= (on ENST00000302987 / NM_172217.5; = p.L185= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1229880361, COSV100268240; called by muse, mutect2
- IRAK1BP1 | c.72G>A p.E24= | Silent (SNP) | VAF 5/112 reads (4%) | catalogued as rs1467655410, COSV64047854; called by muse, mutect2
- MKRN3 | c.783C>T p.L261= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV58812508; called by muse, mutect2, varscan2
- MUSK | c.2034C>A p.L678= | Silent (SNP) | VAF 18/392 reads (5%) | catalogued as COSV99505249; called by muse, mutect2
- NLRP11 | c.1548G>A p.P516= | Silent (SNP) | VAF 17/322 reads (5%) | catalogued as rs757674862, COSV100789821; called by muse, mutect2
- NTS | c.442C>T p.L148= | Silent (SNP) | VAF 20/411 reads (5%) | catalogued as COSV99755234; called by muse, mutect2
- OR8H2 | c.132G>A p.V44= | Silent (SNP) | VAF 26/816 reads (3%) | called by muse, mutect2
- PCDHA11 | c.405C>G p.L135= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV56518377, COSV56520363; called by muse, mutect2
- PCDHB5 | c.2046C>A p.A682= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs782638971, COSV99167789, COSV99169695; called by muse, mutect2
- PRX | c.1065G>A p.L355= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV52529507; called by muse, mutect2
- PTN | c.249G>A p.Q83= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV100781048; called by muse, mutect2
- RPL3L | c.462G>A p.K154= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99238533; called by muse, mutect2
- SLC26A2 | c.1101G>T p.G367= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV99640432; called by muse, mutect2
- ST6GALNAC3 | c.276G>A p.Q92= | Silent (SNP) | VAF 16/360 reads (4%) | catalogued as COSV60343823; called by muse, mutect2
- TC2N | c.951G>A p.R317= | Silent (SNP) | VAF 14/316 reads (4%) | catalogued as rs778120721, COSV61747997; called by muse, mutect2
- TERT | c.1719C>G p.L573= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV57204320, COSV99721287; called by muse, mutect2
- TRIML1 | c.390G>A p.E130= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1390911056, COSV100205978, COSV100206370; called by muse, mutect2
- ZKSCAN4 | c.1602G>A p.Q534= | Silent (SNP) | VAF 17/199 reads (9%) | catalogued as COSV101043590; called by muse, mutect2
- ZNF585B | c.1173C>T p.F391= | Silent (SNP) | VAF 18/369 reads (5%) | catalogued as COSV100459683; called by muse, mutect2
- AP000769.3 | chr11:65501983 G>C | 5'Flank (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- AP000769.5 | chr11:65500966 G>C | 5'Flank (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- GP6 | c.*497C>T | 3'UTR (SNP) | VAF 22/318 reads (7%) | catalogued as COSV100117792; called by muse, mutect2
- TPM3 | c.244-6860C>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1343075156, COSV99666717; called by muse, mutect2
- ZNF99 | c.*563C>T | 3'UTR (SNP) | VAF 28/589 reads (5%) | catalogued as rs1222941226, COSV101233992; called by muse, mutect2
